Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A39K, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A39K-01A (Primary Tumor).

IIHAA Discrepancy		

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

1) LYMPH NODE (EXCISION): METASTATIC PAPILLARY THYROID CARCINOMA INVOLVING A LYMPH NODE.

2) LEFT LOBE THYROID (TOTAL THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy

1CB-0-3

TUMOR SITE:

Left lobe

carcinoma, papillary thyroid 8260/3
Site: thyroid, NOS C73.9
pw
9/14/11

HISTOLOGIC TYPE:

Papillary carcinoma

TUMOR SIZE:

4.0 cm in greatest dimension

FOCALITY:

Multifocal (including right lobe)

LYMPH NODES:

Metastatic carcinoma in 11 of 14 lymph nodes

EXTENT OF INVASION

PRIMARY TUMOR:

pT3: Tumor >4 cm, with minimal extrathyroidal extension

REGIONAL LYMPH NODES:

pN1a: Nodal metastasis to level VI (pretracheal, paratracheal, and prelaryngeal/Delphin) nodes

DISTANT METASTASIS:

pMx: Cannot be assessed

MARGINS:

Involved by invasive carcinoma (inked margin lower left lobe)

VENOUS/LYMPHATIC INVASION:

Present

ADDITIONAL PATHOLOGIC FINDINGS:

A parathyroid gland is also identified.

Source: NCI Genomic Data Commons file 4473cd71-0ef9-4db4-879d-ecec8b1bc1e2 (TCGA-ET-A39K.75057843-C8BE-4632-81AF-B6D383A10036.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).